Somatic mutation profile of tumor specimen 0DYNNU from CCDI case PBCSSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,194 days).
Specimen 0DYNNU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9fd3cd0-bb1d-476c-bf40-7695e8213d91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYNMN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e04d6c-84ad-4868-b354-eaf8d173202d

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP5F1A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 123/583 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs765711330, COSV56360072; called by muse, mutect2, varscan2
- MYCBP | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 139/697 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs764697452, COSV66920351; called by muse, mutect2, varscan2
- PEAK3 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1456479382; called by muse, mutect2
- UQCRC2 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 262/542 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV51674169; called by muse, mutect2, varscan2
- ACCSL | c.827T>A p.L276Q | Missense Mutation (SNP) | VAF 170/406 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 56/1552 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CNTLN | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 109/557 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTRL | c.369A>T p.K123N | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KATNAL1 | c.430_431del p.K144Efs*2 | Frame Shift Del (DEL) | VAF 176/409 reads (43%) | called by mutect2, varscan2
- RAD1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- RASEF | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 74/482 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TMEM144 | c.847T>C p.F283L | Missense Mutation (SNP) | VAF 76/718 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AEBP2 | c.1071C>T p.N357= | Silent (SNP) | VAF 106/817 reads (13%) | called by muse, mutect2, varscan2
- CDHR5 | c.1632G>A p.P544= (on ENST00000358353 / NM_001171968.2; = p.P550= on NM_021924.5) | Silent (SNP) | VAF 36/359 reads (10%) | catalogued as rs770305702; called by muse, mutect2, varscan2
- COBLL1 | c.312G>C p.G104= (on ENST00000392717; = p.G66= on NM_014900.5) | Silent (SNP) | VAF 61/443 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.37275T>C p.G12425= | Silent (SNP) | VAF 77/529 reads (15%) | catalogued as rs764503526, COSV101199334; called by muse, mutect2, varscan2
- TRIM8 | c.435C>T p.C145= | Silent (SNP) | VAF 42/214 reads (20%) | catalogued as rs756923782; called by muse, varscan2
- BRAT1 | c.1016-53C>T | Intron (SNP) | VAF 15/115 reads (13%) | catalogued as rs1163456436; called by muse, mutect2, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, varscan2
